Somatic mutation profile of tumor specimen C3L-04849-02 (aliquot CPT0248520006) from CPTAC case C3L-04849, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 63.2 years (23,099 days).
Specimen C3L-04849-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c39b2d39-e330-4518-80a5-7ccb811b86af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04849-31 (Blood Derived Normal), aliquot CPT0248540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be898ced-888d-431f-9e50-4a5ad44089df

The open-access MAF lists 203 somatic variants for this specimen: 138 protein-altering or splice-affecting, 42 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 42, Intron 11, Nonsense Mutation 7, Frame Shift Ins 3, Splice Region 3, RNA 3, 5'UTR 3, 3'UTR 3, Splice Site 3, Frame Shift Del 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 11/238 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2
- TP53 | c.730G>A p.G244S | Missense Mutation (SNP) | VAF 57/367 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAP2 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as rs377598564; called by muse, mutect2, varscan2
- AFF1 | c.3538G>A p.V1180M | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.175); catalogued as rs1198359386, COSV57119672; called by muse, mutect2, varscan2
- ANK3 | c.9965C>A p.S3322Y | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV55051953; called by muse, mutect2, varscan2
- ARHGAP31 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 41/451 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs374928307, COSV99957504; called by muse, mutect2
- ATAD3A | c.328T>C p.W110R | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1619815, COSV59233815; called by muse, mutect2
- BOD1L1 | c.5275G>A p.G1759S | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1399124146; called by muse, mutect2, varscan2
- CARD11 | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62718328; called by muse, mutect2
- CCT6A | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV99303500; called by muse, mutect2, varscan2
- DPP3 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as rs201663539, COSV100855387; called by muse, mutect2, varscan2
- EFHD1 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs757013631, COSV51133563, COSV51134313; called by muse, mutect2, varscan2
- EIF3G | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99463034; called by muse, mutect2
- ELANE | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 155/387 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99311570; called by muse, mutect2, varscan2
- EMSY | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.102); catalogued as rs775086711; called by muse, mutect2, varscan2
- EPHA4 | c.1421A>T p.Y474F | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56042958; called by muse, mutect2
- EPHB1 | c.2536C>A p.P846T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67673321; called by mutect2, varscan2
- EWSR1 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs751377720, COSV58421918; called by muse, mutect2, varscan2
- FASTKD5 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV53906279; called by muse, mutect2, varscan2
- FAT3 | c.4972C>T p.R1658C | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs201013393; called by muse, mutect2, varscan2
- FBLN7 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.605); catalogued as rs749054176, COSV55616109; called by muse, varscan2
- FN1 | c.3155C>A p.P1052Q | Missense Mutation (SNP) | VAF 44/416 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.821); catalogued as COSV60553749; called by muse, mutect2, varscan2
- GDF6 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs1317137705; called by muse, mutect2, varscan2
- GLIPR1L2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1366043607, COSV100248784; called by muse, mutect2, varscan2
- GPRC5A | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs778793935; called by muse, mutect2, varscan2
- HELZ2 | c.6727C>T p.R2243C (on ENST00000467148 / NM_001037335.2; = p.R1674C on NM_033405.3) | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756636547; called by muse, mutect2
- HPS6 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 30/621 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs141011469; called by muse, mutect2
- IFFO1 | c.1483C>G p.L495V (on ENST00000396840 / NM_001330324.2; = p.L498V on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/329 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1030882793; called by muse, mutect2, varscan2
- IL1RL2 | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51818360; called by muse, mutect2, varscan2
- ITGA8 | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 75/327 reads (23%) | catalogued as rs1336722162, COSV65224234; called by muse, mutect2, varscan2
- KCNJ3 | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs201650481, COSV54544929, COSV99716544; called by muse, mutect2, varscan2
- KCNQ3 | c.2545G>A p.G849S | Missense Mutation (SNP) | VAF 78/527 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.149); catalogued as rs761201259, COSV66468748, COSV66481582; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNT1 | c.1558G>A p.G520S (on ENST00000488444; = p.G539S on NM_020822.3) | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs1035980360; called by muse, mutect2, varscan2
- KCTD7 | c.493C>T p.R165W (on ENST00000275532; = p.A178V on NM_153033.5) | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as rs368001837; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LARGE1 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 108/478 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); catalogued as rs749980997, COSV61662758; called by muse, mutect2, varscan2
- LTBP1 | c.2870-4G>C | Splice Region (SNP) | VAF 25/228 reads (11%) | catalogued as rs371068444; called by muse, mutect2, varscan2
- LY9 | c.959G>T p.C320F | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs763110172; called by muse, mutect2, varscan2
- MUC12 | c.5416G>A p.V1806I (on ENST00000379442; = p.V1663I on NM_001164462.1) | Missense Mutation (SNP) | VAF 170/890 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.101); catalogued as rs530559723; called by muse, mutect2, varscan2
- MYH2 | c.3415G>A p.E1139K | Missense Mutation (SNP) | VAF 105/565 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55448051; called by muse, mutect2, varscan2
- MYH7 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as rs397516117, COSV62516619, COSV62523490; ClinVar: uncertain significance; called by muse, mutect2
- NAALADL2 | c.2280G>T p.E760D | Missense Mutation (SNP) | VAF 18/477 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV101495518; called by muse, mutect2
- OR2L2 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 101/261 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs138166879; called by muse, mutect2, varscan2
- OR4C3 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781747610; called by muse, mutect2, varscan2
- PELP1 | c.2351C>G p.S784C | Missense Mutation (SNP) | VAF 28/248 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs756096509; called by muse, mutect2, varscan2
- PHF20 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756788600; called by muse, mutect2, varscan2
- PPP1R9B | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 19/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1209090814; called by muse, mutect2
- PROKR2 | c.1023G>A p.M341I | Missense Mutation (SNP) | VAF 122/464 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54086464; called by muse, mutect2, varscan2
- PRSS37 | c.34+1G>T p.X12_splice | Splice Site (SNP) | VAF 30/130 reads (23%) | catalogued as rs762920669; called by muse, mutect2, varscan2
- RANBP17 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs199913315; called by muse, mutect2, varscan2
- RC3H2 | c.288G>T p.E96D | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.899); catalogued as rs755346971; called by muse, mutect2, varscan2
- RCVRN | c.357G>C p.K119N | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56841976; called by muse, mutect2
- SLC25A13 | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 43/439 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55714454; called by muse, mutect2, varscan2
- SNTG2 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 27/344 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57991574; called by muse, mutect2
- STK26 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 43/143 reads (30%) | catalogued as rs1477057424; called by muse, mutect2, varscan2
- TGFA | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1377948470; called by muse, mutect2, varscan2
- TMEM250 | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 131/359 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as rs756646589; called by muse, varscan2
- TNRC6A | c.4382A>T p.D1461V | Missense Mutation (SNP) | VAF 120/493 reads (24%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as rs1383380728; called by muse, mutect2, varscan2
- TP53 | c.399del p.M133Ifs*37 | Frame Shift Del (DEL) | VAF 88/287 reads (31%) | catalogued as COSV52873049, COSV53485948, COSV99037126; called by mutect2, pindel, varscan2
- VWA3B | c.3769C>G p.L1257V | Missense Mutation (SNP) | VAF 43/345 reads (12%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as rs201018704; called by muse, mutect2, varscan2
- ZC3H3 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1352895825; called by muse, mutect2, varscan2
- ZDHHC11 | c.1112C>A p.T371N | Missense Mutation (SNP) | VAF 111/361 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV52068196; called by muse, mutect2, varscan2
- ZNF143 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); catalogued as rs761251534; called by muse, mutect2, varscan2
- ZNF366 | c.1196A>G p.D399G | Missense Mutation (SNP) | VAF 24/367 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs758789953; called by muse, mutect2
- ZNF423 | c.470G>A p.R157H (on ENST00000563137 / NM_001379286.1; = p.R149H on NM_015069.4) | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766243231; called by muse, mutect2, varscan2
- ZNF552 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as rs777421103; called by muse, mutect2, varscan2
- ZNF750 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs977516372; called by muse, mutect2, varscan2
- ZNF837 | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 52/381 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1209898215; called by muse, mutect2, varscan2
- ABCA13 | c.8452_8454del p.N2818del | In Frame Del (DEL) | VAF 54/130 reads (42%) | called by mutect2, pindel, varscan2
- ABCE1 | c.1246A>G p.I416V | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.458); called by muse, mutect2
- AGMAT | c.739G>T p.A247S | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- APBB1 | c.1779G>T p.L593F | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- APCDD1 | c.330dup p.G111Wfs*78 | Frame Shift Ins (INS) | VAF 91/325 reads (28%) | called by mutect2, pindel, varscan2
- ARIH2 | c.260C>A p.S87Y | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- ATAD1 | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ATP8B3 | c.3440T>A p.I1147N | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- BBS12 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 21/164 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BBS4 | c.503A>G p.D168G | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- C16orf78 | c.602A>C p.K201T | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- C9orf131 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2
- CAD | c.6379-6C>A | Splice Region (SNP) | VAF 58/429 reads (14%) | called by muse, mutect2, varscan2
- CBARP | c.828+1G>A p.X276_splice (on ENST00000382477; = p.X256_splice on NM_152769.3) | Splice Site (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- CCP110 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- CFAP20DC | c.1564G>A p.D522N (on ENST00000482387 / NM_001351530.2; = p.D397N on NM_198463.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/190 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- COL1A2 | c.3440A>G p.E1147G | Missense Mutation (SNP) | VAF 74/389 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DCAF13 | c.414G>C p.M138I | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DLGAP2 | c.829A>T p.R277W | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DNAAF5 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 12/279 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.052); called by muse, mutect2
- DOCK5 | c.4984A>G p.I1662V | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FAT2 | c.10029A>T p.V3343= | Splice Region (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- GBP6 | c.1672G>T p.D558Y | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- GCC1 | c.545T>C p.M182T | Missense Mutation (SNP) | VAF 90/354 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GLI2 | c.3511C>T p.P1171S (on ENST00000361492 / NM_001374353.1; = p.P1188S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HGSNAT | c.392A>G p.E131G | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HMCN2 | c.14595C>G p.D4865E | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- KCNC4 | c.430T>A p.C144S | Missense Mutation (SNP) | VAF 129/690 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KDM4C | c.2331G>A p.M777I | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KLHL4 | c.1114A>T p.R372* | Nonsense Mutation (SNP) | VAF 15/69 reads (22%) | called by muse, mutect2, varscan2
- LAMA5 | c.9251G>C p.G3084A | Missense Mutation (SNP) | VAF 16/419 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); called by muse, mutect2
- LRRC7 | c.3742T>A p.Y1248N (on ENST00000651989 / NM_001370785.2; = p.Y1215N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MED24 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- MEGF10 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MFSD8 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 15/316 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- MPDZ | c.4541A>G p.H1514R | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- MUC20 | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 211/864 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MYOM2 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NCAPD3 | c.2793C>A p.C931* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- NLN | c.1400T>C p.M467T | Missense Mutation (SNP) | VAF 46/285 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- OR2L2 | c.502T>A p.C168S | Missense Mutation (SNP) | VAF 38/229 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR5D14 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- OSBPL10 | c.1171G>T p.G391C | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- OSBPL1A | c.2380G>C p.D794H (on ENST00000319481 / NM_080597.4; = p.D281H on NM_018030.4) | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- OSBPL6 | c.2288_2289del p.L763Hfs*11 | Frame Shift Del (DEL) | VAF 33/132 reads (25%) | called by mutect2, pindel, varscan2
- PCDHA11 | c.1744C>G p.R582G | Missense Mutation (SNP) | VAF 95/557 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- PCDHB3 | c.1256T>C p.I419T | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- POGZ | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PTK2 | c.2563-1G>A p.X855_splice | Splice Site (SNP) | VAF 40/147 reads (27%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.1133T>A p.L378* | Nonsense Mutation (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- RBM39 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- RHPN1 | c.1784G>C p.R595T | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.033); called by muse, mutect2
- ROR1 | c.136dup p.W46Lfs*6 | Frame Shift Ins (INS) | VAF 89/272 reads (33%) | called by mutect2, pindel, varscan2
- SGIP1 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, varscan2
- SGIP1 | c.2273A>T p.D758V | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- SHISA3 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 20/148 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.01); called by muse, mutect2
- SLC17A9 | c.725G>A p.W242* | Nonsense Mutation (SNP) | VAF 84/339 reads (25%) | called by muse, mutect2, varscan2
- SLC1A1 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT tolerated (0.96); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SLC35B1 | c.592G>A p.V198I (on ENST00000649906; = p.V161I on NM_005827.4) | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPAG5 | c.1240G>C p.E414Q | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPATA31D1 | c.1322A>T p.Q441L | Missense Mutation (SNP) | VAF 66/522 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SPTAN1 | c.3489G>T p.M1163I | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- ST6GALNAC2 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 11/89 reads (12%) | PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TAS2R3 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.123); called by muse, mutect2
- TMPRSS15 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 94/254 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TRBV28 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.188); called by muse, mutect2
- TRERF1 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- VPS13C | c.2898dup p.H967Sfs*2 (on ENST00000644861 / NM_020821.3; = p.H924Sfs*2 on NM_017684.5) | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- WRN | c.3005G>C p.S1002T | Missense Mutation (SNP) | VAF 63/300 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF117 | c.784T>A p.S262T | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZP1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2
- ABCC10 | c.2388G>A p.L796= (on ENST00000372530 / NM_001198934.2; = p.L768= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as rs1490626646; called by muse, mutect2, varscan2
- ACSM1 | c.300C>T p.N100= | Silent (SNP) | VAF 132/597 reads (22%) | catalogued as rs150200803; called by muse, mutect2, varscan2
- AKT1S1 | c.639C>T p.P213= (on ENST00000344175 / NM_001098633.4; = p.P233= on NM_032375.5) | Silent (SNP) | VAF 11/266 reads (4%) | called by muse, mutect2
- AMPH | c.717C>T p.A239= | Silent (SNP) | VAF 80/363 reads (22%) | catalogued as rs761825136, COSV100342480; called by muse, mutect2, varscan2
- APCDD1 | c.1158C>T p.N386= | Silent (SNP) | VAF 38/367 reads (10%) | catalogued as rs778685004, COSV62372160; called by muse, mutect2, varscan2
- ASNS | c.1254C>T p.V418= | Silent (SNP) | VAF 7/159 reads (4%) | catalogued as COSV51556125; called by muse, mutect2
- BAHCC1 | c.7902C>T p.G2634= | Silent (SNP) | VAF 65/428 reads (15%) | catalogued as rs782077769, COSV57024605; called by muse, mutect2, varscan2
- C19orf44 | c.1470T>A p.S490= | Silent (SNP) | VAF 214/559 reads (38%) | called by muse, mutect2, varscan2
- C2orf42 | c.1227A>G p.K409= | Silent (SNP) | VAF 35/284 reads (12%) | catalogued as COSV52448885; called by muse, mutect2, varscan2
- CCDC198 | c.852G>A p.E284= | Silent (SNP) | VAF 41/259 reads (16%) | catalogued as COSV99371313; called by muse, mutect2, varscan2
- DCHS2 | c.1347G>A p.E449= | Silent (SNP) | VAF 76/167 reads (46%) | catalogued as rs1467443102; called by muse, mutect2, varscan2
- EIF6 | c.231C>T p.T77= | Silent (SNP) | VAF 169/398 reads (42%) | catalogued as rs752870740; called by muse, mutect2, varscan2
- ELOA2 | c.2169C>T p.P723= | Silent (SNP) | VAF 193/672 reads (29%) | catalogued as rs888416579; called by muse, mutect2, varscan2
- FAM227B | c.1146T>C p.R382= | Silent (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- KCNH8 | c.363A>G p.G121= | Silent (SNP) | VAF 40/234 reads (17%) | called by muse, mutect2, varscan2
- KLHL3 | c.1422G>A p.A474= | Silent (SNP) | VAF 47/280 reads (17%) | catalogued as rs747378413; called by muse, mutect2, varscan2
- MAP3K19 | c.3804T>C p.A1268= | Silent (SNP) | VAF 32/379 reads (8%) | called by muse, mutect2
- MEX3D | c.1161G>A p.T387= | Silent (SNP) | VAF 26/159 reads (16%) | catalogued as rs754188319; called by muse, mutect2, varscan2
- NOTCH1 | c.7476G>A p.S2492= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as rs952060677; called by muse, mutect2
- OBP2A | c.46C>T p.L16= | Silent (SNP) | VAF 32/350 reads (9%) | called by muse, varscan2
- OR1L8 | c.489G>C p.L163= | Silent (SNP) | VAF 76/315 reads (24%) | catalogued as COSV59185770; called by muse, mutect2, varscan2
- PCDH17 | c.1998C>A p.T666= | Silent (SNP) | VAF 81/486 reads (17%) | catalogued as rs201266461, COSV64978588; called by muse, mutect2, varscan2
- PIGT | c.1218C>T p.G406= | Silent (SNP) | VAF 15/264 reads (6%) | catalogued as rs1568950918; called by muse, mutect2
- PLXNA3 | c.1647G>A p.V549= | Silent (SNP) | VAF 18/201 reads (9%) | called by muse, mutect2
- POLG2 | c.321G>T p.R107= | Silent (SNP) | VAF 19/180 reads (11%) | catalogued as rs1355396304; called by muse, mutect2, varscan2
- PPFIBP2 | c.1383A>T p.T461= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as COSV100206297; called by muse, mutect2
- PRSS36 | c.1998C>T p.I666= | Silent (SNP) | VAF 15/296 reads (5%) | called by muse, mutect2
- RBMS3 | c.1206G>A p.Q402= (on ENST00000383767 / NM_001003793.3; = p.Q386= on NM_014483.3) | Silent (SNP) | VAF 44/215 reads (20%) | called by muse, mutect2, varscan2
- RGPD4 | c.1428A>G p.A476= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs199557356; called by mutect2, varscan2
- SATB1 | c.1233G>A p.K411= | Silent (SNP) | VAF 90/185 reads (49%) | catalogued as rs919820652; called by muse, mutect2, varscan2
- SDF2 | c.69C>A p.V23= | Silent (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- SDK1 | c.3018G>A p.Q1006= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV67360301; called by muse, varscan2
- SEMA4G | c.390C>A p.L130= | Silent (SNP) | VAF 26/426 reads (6%) | called by muse, mutect2
- SKOR2 | c.1215C>T p.F405= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- SMAD6 | c.942T>C p.G314= | Silent (SNP) | VAF 46/238 reads (19%) | called by muse, mutect2, varscan2
- SMC4 | c.192C>T p.S64= | Silent (SNP) | VAF 63/288 reads (22%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.750C>T p.V250= | Silent (SNP) | VAF 186/613 reads (30%) | called by muse, mutect2, varscan2
- SSTR1 | c.150C>G p.T50= | Silent (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- TECPR1 | c.1575G>A p.P525= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs371532016, COSV65783428; called by muse, mutect2, varscan2
- TOP1 | c.657C>T p.F219= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV63694455; called by muse, mutect2, varscan2
- TRIM28 | c.237C>T p.R79= | Silent (SNP) | VAF 12/297 reads (4%) | called by muse, mutect2
- ZSCAN10 | c.1983G>A p.G661= (on ENST00000252463; = p.G716= on NM_032805.3) | Silent (SNP) | VAF 27/237 reads (11%) | called by muse, mutect2, varscan2
- ABCA10 | c.35-973C>T | Intron (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- AC093642.3 | n.3084C>A | RNA (SNP) | VAF 60/580 reads (10%) | called by muse, varscan2
- AC244517.10 | c.36-8717G>C | Intron (SNP) | VAF 77/355 reads (22%) | called by muse, mutect2, varscan2
- ACOT8 | c.262+1175A>T | Intron (SNP) | VAF 92/357 reads (26%) | called by muse, mutect2, varscan2
- ARPP21 | c.2032+574G>A | Intron (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- ARSA | c.685-17C>T | Intron (SNP) | VAF 38/127 reads (30%) | called by muse, mutect2, varscan2
- BNIP1 | c.178-2642C>T | Intron (SNP) | VAF 24/145 reads (17%) | catalogued as rs754756627; called by muse, mutect2, varscan2
- CD40 | c.*5G>A | 3'UTR (SNP) | VAF 41/341 reads (12%) | called by muse, mutect2, varscan2
- EPDR1 | c.-121T>G | 5'UTR (SNP) | VAF 16/348 reads (5%) | called by muse, mutect2
- GAPVD1 | c.2429-1829C>T | Intron (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- GRHL2 | c.20+10T>G | Intron (SNP) | VAF 20/655 reads (3%) | called by muse, mutect2
- HOXA4 | c.*13C>G | 3'UTR (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.9C>T | RNA (SNP) | VAF 56/139 reads (40%) | catalogued as rs745429172; called by muse, mutect2, varscan2
- MIR515-2 | n.49C>A | RNA (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- MRPL37 | chr1:54220768 A>T | 3'Flank (SNP) | VAF 128/417 reads (31%) | called by muse, mutect2
- MRPS36 | c.-13C>T | 5'UTR (SNP) | VAF 49/272 reads (18%) | catalogued as rs1443695888; called by muse, mutect2, varscan2
- OPA1 | c.1478-20C>A | Intron (SNP) | VAF 72/234 reads (31%) | called by muse, mutect2, varscan2
- PIN1 | c.58+1497A>G | Intron (SNP) | VAF 25/170 reads (15%) | catalogued as rs751440071; called by muse, mutect2, varscan2
- SEPTIN9 | c.*250T>C | 3'UTR (SNP) | VAF 58/226 reads (26%) | called by muse, mutect2, varscan2
- SNX5 | c.-190C>G | 5'UTR (SNP) | VAF 37/207 reads (18%) | called by muse, varscan2
- STX4 | chr16:31033426 A>G | 5'Flank (SNP) | VAF 36/376 reads (10%) | called by muse, mutect2
- SYBU | chr8:109645250 A>G | 5'Flank (SNP) | VAF 34/436 reads (8%) | called by muse, mutect2
- UQCRB | c.259-141G>A | Intron (SNP) | VAF 12/288 reads (4%) | called by muse, mutect2
